Somatic mutation profile of tumor specimen TCGA-DD-AACA-02A (aliquot TCGA-DD-AACA-02A-11D-A40R-10) from TCGA case TCGA-DD-AACA, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 65.6 years (23,973 days).
Specimen TCGA-DD-AACA-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0d449d0-04a2-47b5-afc1-c5420443d51b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACA-10A (Blood Derived Normal), aliquot TCGA-DD-AACA-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab556a82-ecee-4bc3-ba35-06cef88b9787

The open-access MAF lists 134 somatic variants for this specimen: 105 protein-altering or splice-affecting, 27 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 27, Nonsense Mutation 9, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, 5'UTR 1, Splice Site 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 111/273 reads (41%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 47/120 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV99699870; called by muse, mutect2, varscan2
- ADAM28 | c.1772A>C p.E591A | Missense Mutation (SNP) | VAF 79/102 reads (77%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.698); catalogued as COSV99738814; called by muse, mutect2, varscan2
- ADAM30 | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101023886; called by muse, mutect2, varscan2
- ADAMTS12 | c.1973G>T p.C658F | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100711078; called by muse, mutect2, varscan2
- ADCY2 | c.1107A>G p.I369M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100603025; called by muse, mutect2, varscan2
- ADGRB2 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 86/100 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.276); catalogued as COSV99927083; called by muse, mutect2, varscan2
- APOA1 | c.485A>C p.Q162P | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs780347391, COSV99369293; called by muse, mutect2, varscan2
- C5orf22 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs745442454, COSV57599943; called by muse, mutect2, varscan2
- CAMK2A | c.1339G>A p.A447T (on ENST00000348628 / NM_171825.2; = p.A458T on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as rs748774194, COSV100652046; called by muse, mutect2
- CDCP1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 85/169 reads (50%) | catalogued as COSV99944083; called by muse, mutect2, varscan2
- CDH15 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.918); catalogued as rs773943777, COSV57024818; called by muse, mutect2, varscan2
- CDH2 | c.181A>T p.S61C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV99297103; called by muse, mutect2, varscan2
- CDH7 | c.504G>A p.V168= | Splice Region (SNP) | VAF 52/98 reads (53%) | catalogued as COSV100542526; called by muse, mutect2, varscan2
- CDKN1B | c.275del p.P92Rfs*27 | Frame Shift Del (DEL) | VAF 234/629 reads (37%) | catalogued as COSV57430859; called by mutect2, pindel, varscan2
- CHUK | c.1950A>G p.I650M | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as COSV100957293; called by muse, mutect2, varscan2
- CIRBP | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV58011635; called by muse, mutect2, varscan2
- CNTNAP2 | c.1088A>T p.N363I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.307); catalogued as COSV100673571; called by muse, mutect2, varscan2
- COL11A1 | c.3352C>A p.P1118T | Missense Mutation (SNP) | VAF 93/194 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.417); catalogued as COSV62192162; called by muse, mutect2, varscan2
- COL4A4 | c.2323C>A p.L775I | Missense Mutation (SNP) | VAF 81/176 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV100307896; called by muse, mutect2, varscan2
- COL5A1 | c.3656G>A p.G1219D | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100880039; called by muse, mutect2, varscan2
- CUBN | c.2620G>A p.V874I | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0.024); catalogued as COSV100912805; called by muse, mutect2, varscan2
- CYP1A1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1429298968; called by muse, mutect2
- DDX6 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 91/351 reads (26%) | catalogued as COSV50588244; called by muse, mutect2, varscan2
- DEFB129 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as COSV55731043, COSV99857470; called by muse, mutect2, varscan2
- DTNBP1 | c.568A>G p.M190V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.039); catalogued as rs536290179, COSV100161206; called by muse, mutect2, varscan2
- EFR3A | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 27/64 reads (42%) | catalogued as COSV99603056; called by muse, mutect2, varscan2
- FEZF2 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 38/96 reads (40%) | catalogued as COSV51862718, COSV99334780; called by muse, mutect2, varscan2
- FFAR2 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV99876085; called by muse, mutect2, varscan2
- FILIP1L | c.2071G>T p.E691* (on ENST00000354552 / NM_182909.3; = p.E451* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100497427; called by muse, mutect2, varscan2
- FLG | c.4958C>T p.S1653L | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as COSV100911635; called by muse, mutect2, varscan2
- FLI1 | c.451T>A p.L151M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99858169; called by muse, varscan2
- FNDC1 | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.017); catalogued as rs772608315, COSV51939704, COSV51944003; called by muse, mutect2, varscan2
- FOXD4L5 | c.334T>A p.S112T | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101073296; called by muse, mutect2, varscan2
- FRMD4B | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101273475; called by muse, mutect2, varscan2
- FYB2 | c.1701A>G p.L567= | Splice Region (SNP) | VAF 40/85 reads (47%) | catalogued as COSV100599579; called by muse, mutect2, varscan2
- GABRA6 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV50877496; called by muse, mutect2, varscan2
- GGT1 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as COSV99958972; called by muse, mutect2, varscan2
- GRID1 | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.355); catalogued as rs762175531, COSV60020849; called by muse, mutect2, varscan2
- GYS1 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs933420343, COSV54402838; called by muse, mutect2, varscan2
- HAAO | c.152G>A p.G51D | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99685408; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.227A>T p.D76V (on ENST00000354667 / NM_031243.3; = p.D64V on NM_002137.4) | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100523029; called by muse, varscan2
- IGKV1D-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 33/274 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs747996565; called by muse, mutect2, varscan2
- INHBE | c.445A>G p.R149G | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99875301; called by muse, mutect2, varscan2
- IZUMO1 | c.826T>C p.S276P | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV99710836; called by muse, mutect2, varscan2
- KCND3 | c.249C>A p.F83L | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100138082, COSV56185047; called by muse, mutect2, varscan2
- KDM2B | c.2390A>T p.D797V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100997689; called by muse, mutect2, varscan2
- KIF26B | c.5419C>T p.R1807C | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1320589019, COSV100832586; called by muse, mutect2, varscan2
- KIT | c.2126C>A p.S709* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as COSV99855508; called by muse, mutect2, varscan2
- LAMA2 | c.5699T>C p.L1900S | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101370518; called by muse, mutect2, varscan2
- LRRC43 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100336587; called by muse, mutect2
- LRRC43 | c.1062G>A p.M354I | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100337018; called by muse, mutect2, varscan2
- MED12 | c.3686T>A p.V1229E | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV61335442; called by muse, mutect2, varscan2
- MFF | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 103/243 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); catalogued as COSV100449339; called by muse, mutect2, varscan2
- MTRF1L | c.377A>G p.E126G | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs774580344, COSV100922462; called by muse, mutect2, varscan2
- MYEOV | c.226T>C p.S76P | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100456659; called by muse, mutect2, varscan2
- MYO18A | c.4936C>T p.R1646W | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs200860055; called by muse, mutect2, varscan2
- NAPA | c.653T>G p.M218R | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99645775; called by muse, mutect2, varscan2
- NARS1 | c.199A>G p.K67E | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV99900760; called by muse, mutect2, varscan2
- NAV2 | c.2659A>G p.M887V (on ENST00000396087 / NM_001244963.2; = p.M864V on NM_145117.5) | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs758639103, COSV100587242; called by muse, mutect2
- NDNF | c.179C>G p.T60R | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV101113187; called by muse, mutect2, varscan2
- NLRP7 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.028); catalogued as rs752841539, COSV100052791; called by muse, mutect2, varscan2
- NPLOC4 | c.1411T>G p.F471V | Missense Mutation (SNP) | VAF 61/296 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100480951; called by muse, mutect2, varscan2
- NUP133 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99772992; called by muse, mutect2, varscan2
- OBSCN | c.5714T>A p.L1905Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs781560949, COSV99479413; called by muse, mutect2, varscan2
- PDE6B | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV55325504, COSV99727675; called by muse, mutect2, varscan2
- PER1 | c.1976C>T p.T659I | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as COSV100424602; called by muse, mutect2, varscan2
- PLCL2 | c.2351A>G p.Y784C (on ENST00000615277 / NM_001144382.2; = p.Y658C on NM_015184.5) | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs774032875, COSV101196764; called by muse, mutect2, varscan2
- PLEKHG6 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs1565455686, COSV99164301; called by muse, mutect2, varscan2
- PLG | c.523T>A p.Y175N | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.615); catalogued as COSV99804744; called by muse, mutect2, varscan2
- PSD3 | c.1830-1G>T p.X610_splice | Splice Site (SNP) | VAF 43/59 reads (73%) | catalogued as COSV99676150; called by muse, mutect2, varscan2
- PXK | c.371A>G p.Y124C | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100244491; called by muse, mutect2, varscan2
- PXN | c.1060G>A p.A354T (on ENST00000228307 / NM_001080855.3; = p.A320T on NM_002859.4) | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.195); catalogued as rs548031679, COSV99936405; called by muse, mutect2, varscan2
- RAD50 | c.641A>C p.K214T | Missense Mutation (SNP) | VAF 155/404 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99529051; called by muse, mutect2, varscan2
- RANGAP1 | c.619A>G p.I207V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV100663774; called by muse, mutect2, varscan2
- REPS1 | c.1817A>G p.D606G (on ENST00000450536 / NM_001286611.2; = p.D605G on NM_031922.4) | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.42); PolyPhen benign (0.272); catalogued as COSV57809194; called by muse, mutect2, varscan2
- RTF1 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV101047872; called by muse, mutect2, varscan2
- SLC32A1 | c.1486A>G p.I496V | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.487); catalogued as COSV99462317; called by muse, mutect2, varscan2
- SLC5A5 | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs754164167, COSV55834552, COSV99715104; called by muse, mutect2, varscan2
- SLCO4C1 | c.1529C>A p.S510* | Nonsense Mutation (SNP) | VAF 43/107 reads (40%) | catalogued as COSV100195965; called by muse, mutect2, varscan2
- SMAD7 | c.758T>C p.L253P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100052924; called by muse, mutect2
- SPRR1B | c.59A>C p.Q20P | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs201420448, COSV100198367; called by muse, mutect2, varscan2
- SRC | c.1337C>A p.S446* | Nonsense Mutation (SNP) | VAF 42/88 reads (48%) | catalogued as COSV100658096; called by muse, mutect2, varscan2
- SRL | c.1292T>C p.I431T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as rs765196291, COSV101281343; called by muse, mutect2, varscan2
- SUPT6H | c.1460A>G p.K487R | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV100112857; called by muse, mutect2, varscan2
- TENM1 | c.7730A>T p.K2577M | Missense Mutation (SNP) | VAF 73/83 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100950214; called by muse, mutect2, varscan2
- TGFBI | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.99); catalogued as rs890309873, COSV100526523; called by muse, mutect2, varscan2
- TMBIM6 | c.605A>G p.D202G | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99920722; called by muse, mutect2, varscan2
- TRIOBP | c.2128T>G p.S710A | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.334); catalogued as COSV100730892, COSV60376256; called by muse, mutect2, varscan2
- TTLL3 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 165/373 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100047583; called by muse, mutect2, varscan2
- TYRO3 | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777686; called by muse, mutect2, varscan2
- USP45 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569728; called by muse, mutect2, varscan2
- USP7 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as COSV100784204; called by muse, mutect2, varscan2
- VCAN | c.9163G>C p.V3055L | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99425711, COSV99427560; called by muse, mutect2, varscan2
- VCP | c.71A>C p.N24T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as COSV100734226; called by muse, mutect2, varscan2
- VPS52 | c.1701C>G p.N567K | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101460437; called by muse, mutect2, varscan2
- ZFHX4 | c.7919G>T p.R2640L | Missense Mutation (SNP) | VAF 71/165 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as COSV99263453; called by muse, mutect2, varscan2
- ZFYVE21 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 30/38 reads (79%) | catalogued as COSV99162986; called by muse, mutect2, varscan2
- ZNF512 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.202); catalogued as COSV100820816; called by muse, mutect2, varscan2
- FCGBP | c.8920T>A p.S2974T | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- IGKV1-17 | c.254G>T p.S85I | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); called by muse, varscan2
- LPCAT1 | c.847_849del p.E283del | In Frame Del (DEL) | VAF 29/63 reads (46%) | called by pindel, varscan2
- PCBP2 | c.1046A>G p.Y349C (on ENST00000439930 / NM_001128911.2; = p.Y350C on NM_005016.6) | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); called by muse, mutect2
- PHTF1 | c.1361dup p.M454Ifs*46 | Frame Shift Ins (INS) | VAF 134/384 reads (35%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.4122G>A p.E1374= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as rs1450580267, COSV99899564; called by muse, mutect2, varscan2
- ANOS1 | c.798G>A p.V266= | Silent (SNP) | VAF 36/36 reads (100%) | catalogued as COSV99390947; called by muse, mutect2, varscan2
- BMS1 | c.1668C>T p.C556= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as COSV100996722; called by muse, mutect2, varscan2
- CBLN2 | c.600C>G p.L200= | Silent (SNP) | VAF 52/105 reads (50%) | catalogued as COSV99504443; called by muse, mutect2, varscan2
- COL22A1 | c.708C>A p.T236= | Silent (SNP) | VAF 29/63 reads (46%) | catalogued as COSV100278774; called by muse, mutect2
- DNAH9 | c.11358C>A p.T3786= | Silent (SNP) | VAF 25/26 reads (96%) | catalogued as COSV52346398, COSV99306150; called by muse, mutect2, varscan2
- EPHA8 | c.1716G>A p.K572= | Silent (SNP) | VAF 101/118 reads (86%) | catalogued as COSV51305281; called by muse, mutect2, varscan2
- HEPH | c.684C>T p.L228= (on ENST00000343002; = p.L282= on NM_138737.5) | Silent (SNP) | VAF 112/133 reads (84%) | catalogued as COSV57959803; called by muse, mutect2, varscan2
- KCNA3 | c.1134G>A p.S378= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as rs764449826, COSV63902769; called by muse, mutect2, varscan2
- KIAA0586 | c.3642A>G p.T1214= (on ENST00000619416 / NM_001244190.2; = p.T1153= on NM_014749.5) | Silent (SNP) | VAF 67/88 reads (76%) | catalogued as rs773464253, COSV99708243; called by muse, mutect2, varscan2
- MICALL1 | c.105G>T p.L35= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV99317315; called by muse, mutect2, varscan2
- NAT9 | c.594T>G p.P198= | Silent (SNP) | VAF 70/92 reads (76%) | catalogued as COSV99380080; called by muse, mutect2, varscan2
- PCDHA1 | c.2232G>C p.A744= | Silent (SNP) | VAF 63/163 reads (39%) | catalogued as COSV100974376, COSV100974390; called by muse, mutect2
- PCDHB12 | c.1881C>A p.A627= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV99507947; called by muse, mutect2, varscan2
- PDIA2 | c.1329T>C p.I443= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as rs1198973166, COSV99249889; called by muse, mutect2, varscan2
- PDXDC1 | c.13C>T p.L5= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1174672723, COSV100363213; called by muse, mutect2, varscan2
- PLXNA4 | c.3690G>A p.P1230= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs762844713, COSV100327681; called by muse, mutect2, varscan2
- RAB4A | c.216A>G p.Q72= | Silent (SNP) | VAF 125/305 reads (41%) | catalogued as COSV100797095; called by muse, mutect2, varscan2
- REV3L | c.7941A>G p.K2647= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100725262; called by muse, mutect2, varscan2
- RNF145 | c.1644G>T p.V548= (on ENST00000424310 / NM_001199383.2; = p.V576= on NM_144726.2) | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV99193568; called by muse, mutect2, varscan2
- SIGLEC6 | c.477C>T p.G159= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV100585441; called by muse, mutect2, varscan2
- SLCO5A1 | c.192G>T p.V64= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV99480173; called by muse, mutect2, varscan2
- STXBP5 | c.2748G>A p.V916= (on ENST00000321680 / NM_001127715.2; = p.V880= on NM_139244.4) | Silent (SNP) | VAF 83/208 reads (40%) | catalogued as COSV99470419; called by muse, mutect2, varscan2
- SURF6 | c.1044C>A p.G348= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- TST | c.660T>C p.D220= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as COSV99968203; called by muse, mutect2, varscan2
- ZBTB41 | c.1410A>G p.K470= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs1159840025, COSV100963164; called by muse, mutect2, varscan2
- ZFP91 | c.255C>T p.S85= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as rs924809027; called by muse, mutect2
- INPPL1 | c.*2A>G | 3'UTR (SNP) | VAF 58/138 reads (42%) | catalogued as COSV99996301; called by muse, mutect2, varscan2
- VPS50 | c.-2A>T | 5'UTR (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99298215; called by muse, mutect2, varscan2
